Somatic mutation profile of tumor specimen TCGA-44-A479-01A (aliquot TCGA-44-A479-01A-31D-A24D-08) from TCGA case TCGA-44-A479, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.0 years (27,024 days).
Specimen TCGA-44-A479-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b177a9fa-07e6-44f4-ae06-0c52af71d0ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-A479-10A (Blood Derived Normal), aliquot TCGA-44-A479-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c4c0cde-1001-4581-be34-e70690f2b57c

The open-access MAF lists 306 somatic variants for this specimen: 243 protein-altering or splice-affecting, 57 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 57, Frame Shift Del 8, Nonsense Mutation 7, Splice Site 5, Frame Shift Ins 3, Intron 3, RNA 1, Nonstop Mutation 1, Splice Region 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA4 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs121434552, CM072913, COSV56282434, COSV99039723; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TUBA1A | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 4/107 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as rs1555162323, CM145636, COSV99853818; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCA7 | c.3751G>T p.G1251C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV99566667; called by muse, mutect2, varscan2
- ABCC9 | c.2019G>T p.K673N | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV53972816, COSV99687244; called by muse, mutect2
- ABHD14A-ACY1 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV101352274; called by muse, mutect2, varscan2
- ADAMTS14 | c.2039G>T p.C680F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100941869; called by muse, mutect2, varscan2
- ADGRG4 | c.5017G>T p.G1673C | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99796793; called by muse, mutect2, varscan2
- ADGRL2 | c.2897G>T p.G966V (on ENST00000370717 / NM_001366005.1; = p.G953V on NM_012302.4) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1164753366, COSV54665457, COSV99587647; called by muse, mutect2, varscan2
- ADORA1 | c.233A>T p.H78L | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100526703; called by muse, mutect2, varscan2
- AHNAK | c.13811G>T p.G4604V | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99949610; called by muse, mutect2
- AHNAK2 | c.3768G>T p.M1256I | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as COSV100318949; called by muse, mutect2, varscan2
- AKNA | c.3707A>G p.N1236S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762965662, COSV99801065; called by muse, mutect2, varscan2
- ALDH8A1 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99665019; called by muse, mutect2, varscan2
- ALOX5AP | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as COSV66857886; called by muse, mutect2
- ALX4 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100241308; called by muse, mutect2, varscan2
- AMELX | c.250C>A p.H84N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); catalogued as COSV100499120; called by muse, mutect2, varscan2
- AMER1 | c.3341C>A p.A1114D | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV100367054, COSV57664224, COSV57666418; called by muse, mutect2
- AMOT | c.1346G>T p.R449M (on ENST00000371959 / NM_001113490.1; = p.R40M on NM_133265.3) | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100495555; called by muse, mutect2, varscan2
- AMPD1 | c.1818T>A p.C606* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100815244; called by muse, mutect2, varscan2
- ANK3 | c.10884G>C p.R3628S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.03); catalogued as rs1397398620, COSV99782376; called by muse, mutect2, varscan2
- APMAP | c.1202G>A p.G401D | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99469078; called by muse, mutect2, varscan2
- APOOL | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.695); catalogued as COSV100920949; called by muse, mutect2, varscan2
- BCAS3 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101177099; called by muse, mutect2, varscan2
- BCO2 | c.865G>T p.G289* | Nonsense Mutation (SNP) | VAF 29/109 reads (27%) | catalogued as rs753077371, COSV100730496; called by muse, mutect2, varscan2
- BMP3 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV51085509; called by muse, mutect2
- BOD1L1 | c.2023G>T p.D675Y | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99240427; called by muse, mutect2, varscan2
- BPIFB1 | c.1128C>G p.F376L | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99487612; called by muse, mutect2, varscan2
- BRINP1 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); catalogued as COSV99776934; called by muse, mutect2, varscan2
- BRINP3 | c.668T>A p.L223Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100819473; called by muse, mutect2
- C1QTNF3 | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as COSV51470167; called by muse, mutect2
- C9orf131 | c.2993G>A p.S998N | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.401); catalogued as COSV100398315; called by muse, mutect2, varscan2
- CACNB2 | c.970G>A p.D324N (on ENST00000324631 / NM_201596.3; = p.D269N on NM_000724.4) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99996389; called by muse, mutect2
- CACNG4 | c.504T>A p.S168R | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); catalogued as COSV100047911; called by muse, mutect2
- CAMKK2 | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100243203; called by muse, mutect2
- CAMTA1 | c.2426G>T p.G809V | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); catalogued as COSV100352413, COSV100352692; called by muse, mutect2, varscan2
- CARD8 | c.694G>A p.G232S (on ENST00000651546 / NM_001184900.3; = p.G182S on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370395701; called by muse, mutect2, varscan2
- CCDC80 | c.1539C>A p.S513R | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.691); catalogued as rs1467947237, COSV99245310; called by muse, mutect2, varscan2
- CCDC83 | c.210G>T p.W70C | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99722001; called by muse, mutect2, varscan2
- CCIN | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100631793, COSV100631951; called by muse, mutect2, varscan2
- CCKAR | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99810543; called by muse, mutect2, varscan2
- CCNB3 | c.3164C>A p.T1055N | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99329883; called by muse, mutect2, varscan2
- CDH10 | c.168G>T p.W56C | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1004382589, COSV100053134; called by muse, mutect2, varscan2
- CDH18 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56949181; called by muse, mutect2, varscan2
- CDK16 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99331971; called by muse, mutect2, varscan2
- CEP41 | c.574+1G>T p.X192_splice | Splice Site (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99782936; called by muse, mutect2
- CEP41 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99782938; called by muse, mutect2
- CFAP57 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100764011; called by muse, mutect2, varscan2
- CHST1 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1391430094, COSV100346531, COSV57324224; called by muse, varscan2
- CHST1 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100346422, COSV100346532; called by muse, varscan2
- CMTM5 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758763630, COSV100198207; called by muse, mutect2, varscan2
- COBLL1 | c.3051G>T p.Q1017H (on ENST00000392717; = p.Q979H on NM_014900.5) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV99528691; called by muse, mutect2, varscan2
- COL11A2 | c.3259G>T p.G1087C (on ENST00000341947 / NM_080680.3; = p.G980C on NM_080679.2) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554535; called by muse, mutect2
- COL12A1 | c.1324G>T p.V442L | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100486542; called by muse, mutect2
- COL3A1 | c.3067G>T p.G1023C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100483728, COSV58586939; called by muse, mutect2, varscan2
- COX4I1 | c.403A>G p.K135E | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99495562; called by muse, mutect2, varscan2
- CRELD2 | c.736T>G p.F246V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs1448569693, COSV100078294; called by muse, mutect2, varscan2
- CRISPLD1 | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV100082457; called by muse, mutect2, varscan2
- CSMD3 | c.2192C>A p.T731K (on ENST00000297405 / NM_001363185.1; = p.T627K on NM_052900.3) | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99847723, COSV99851161; called by muse, mutect2, varscan2
- CTNND2 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | catalogued as COSV100481084; called by muse, mutect2, varscan2
- CYP11B2 | c.496A>T p.R166W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs750033578, COSV100011394; called by muse, mutect2, varscan2
- DBH | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755133909, COSV99708133; called by muse, mutect2, varscan2
- DNAH7 | c.10744C>A p.L3582M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417572; called by muse, mutect2
- DNAH9 | c.10736G>A p.R3579K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as COSV99308146, COSV99308527; called by mutect2, varscan2
- DPYS | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as COSV100680122, COSV60908155; called by muse, mutect2, varscan2
- DTD2 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180141; called by muse, mutect2, varscan2
- DZIP1L | c.983A>G p.E328G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100551721; called by muse, mutect2, varscan2
- EDRF1 | c.1934G>T p.G645V (on ENST00000356792 / NM_001202438.2; = p.G611V on NM_015608.2) | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100524014; called by muse, mutect2
- EHBP1 | c.2152A>G p.T718A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV99861881; called by muse, mutect2, varscan2
- FAM78B | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100597805; called by muse, mutect2
- FAR2 | c.917C>A p.T306K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV99479639; called by muse, mutect2
- FBH1 | c.2398+1G>T p.X800_splice (on ENST00000362091 / NM_178150.3; = p.X851_splice on NM_032807.4) | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100758940, COSV100758944; called by muse, mutect2, varscan2
- FBN2 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs779482726, COSV99330673; called by muse, mutect2, varscan2
- FCRL3 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63840465; called by muse, mutect2, varscan2
- FCRLA | c.463G>T p.V155L (on ENST00000367959; = p.V132L on NM_032738.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.408); catalogued as COSV99376630; called by muse, mutect2, varscan2
- FLNC | c.5470G>T p.V1824L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV100368737, COSV57961682; called by muse, mutect2, varscan2
- FZD5 | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54944009; called by muse, mutect2, varscan2
- GABRG1 | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV54949215; called by muse, mutect2
- GABRR3 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101512267, COSV101512357; called by muse, mutect2, varscan2
- GBP7 | c.1366-1G>T p.X456_splice | Splice Site (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99643498; called by muse, mutect2, varscan2
- GFRA1 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV100816160; called by muse, mutect2, varscan2
- GLI2 | c.1880G>C p.R627T (on ENST00000361492 / NM_001374353.1; = p.R644T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100084332; called by muse, mutect2, varscan2
- GPC4 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 58/332 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100895605; called by muse, mutect2, varscan2
- GRIA2 | c.2622C>A p.N874K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52386476, COSV99644602; called by muse, varscan2
- GSDMA | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV100053820; called by mutect2, varscan2
- HEATR4 | c.2810C>G p.P937R | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.157); catalogued as rs763059759, COSV100408118; called by muse, mutect2, varscan2
- HERC2 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV55349970; called by muse, mutect2, varscan2
- HNF4G | c.936T>A p.F312L (on ENST00000354370 / NM_001330561.2; = p.F359L on NM_004133.5) | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV100585033; called by muse, mutect2
- HSD3B1 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99348102; called by muse, mutect2, varscan2
- HSPA1L | c.1022G>A p.G341D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100989458; called by muse, mutect2, varscan2
- HTR1B | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.031); catalogued as COSV100885486; called by muse, mutect2
- IL13RA2 | c.368G>T p.W123L | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV99683380; called by muse, mutect2
- IL2RB | c.466C>A p.Q156K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV99345148; called by muse, mutect2, varscan2
- IPMK | c.1159G>C p.A387P | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100880461; called by muse, mutect2, varscan2
- ITK | c.1258C>A p.Q420K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); catalogued as rs1170207383, COSV101439889; called by muse, mutect2, varscan2
- ITPRID1 | c.1765G>T p.V589L | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV100087536; called by muse, mutect2, varscan2
- JAKMIP1 | c.1124C>A p.A375E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.209); catalogued as COSV51532613, COSV99290794; called by muse, mutect2, varscan2
- KCNH7 | c.2050A>G p.K684E | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV100037787; called by muse, mutect2, varscan2
- KCNJ2 | c.1267C>G p.R423G | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.424); catalogued as COSV99696537; called by muse, mutect2, varscan2
- KCNV2 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765927725, COSV101172645; called by muse, mutect2, varscan2
- KHDRBS3 | c.208-1G>T p.X70_splice | Splice Site (SNP) | VAF 16/66 reads (24%) | catalogued as COSV63415591; called by muse, mutect2, varscan2
- KIAA0408 | c.1821G>A p.M607I | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100847070; called by muse, mutect2, varscan2
- KSR2 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV100351226; called by muse, mutect2, varscan2
- LPCAT2 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.424); catalogued as COSV100045324; called by muse, mutect2
- LRP4 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.31); catalogued as COSV101066889; called by muse, mutect2, varscan2
- LRP4 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.31); catalogued as COSV101066890; called by muse, mutect2, varscan2
- LSM11 | c.1082G>T p.*361Lext*22 | Nonstop Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99644062; called by muse, mutect2
- LTBP1 | c.2129G>T p.W710L (on ENST00000404816 / NM_206943.4; = p.W384L on NM_000627.4) | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100617941; called by muse, mutect2, varscan2
- LUM | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1379050660, COSV99899195; called by muse, mutect2, varscan2
- MAGEA12 | c.369G>C p.K123N | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100757054; called by muse, mutect2
- MATN4 | c.1451G>C p.R484P (on ENST00000372754; = p.R443P on NM_003833.4) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | PolyPhen probably damaging (1); catalogued as COSV100637170, COSV61350811; called by muse, mutect2, varscan2
- MEFV | c.2240C>T p.S747F | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs1175561757, COSV99561310; called by muse, mutect2, varscan2
- MEMO1 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99704719; called by muse, mutect2, varscan2
- MEX3B | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV100314233, COSV61664593; called by muse, mutect2, varscan2
- MGAT5B | c.1516C>G p.P506A (on ENST00000569840 / NM_001199172.2; = p.P504A on NM_144677.3) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100048948; called by muse, mutect2, varscan2
- MPDZ | c.3437G>T p.W1146L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV100057618; called by muse, mutect2, varscan2
- MPPED2 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100813534; called by muse, mutect2, varscan2
- MSH3 | c.2687G>T p.G896V | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99435709; called by muse, mutect2
- MTHFD1L | c.1576G>T p.V526L | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.435); catalogued as COSV100945355; called by muse, mutect2
- MUC16 | c.16151G>T p.S5384I | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV101201726; called by muse, mutect2, varscan2
- MYOT | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99525118; called by muse, mutect2, varscan2
- NALCN | c.4764G>C p.Q1588H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.783); catalogued as COSV99217740; called by muse, mutect2, varscan2
- NALCN | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.87); catalogued as COSV51960026, COSV99214143; called by muse, mutect2, varscan2
- NECTIN1 | c.967G>C p.G323R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99872640; called by muse, mutect2, varscan2
- NKRF | c.1502A>G p.Y501C | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100441892; called by muse, mutect2, varscan2
- NME8 | c.881C>A p.A294D | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99553849, COSV99553898; called by muse, mutect2
- NOBOX | c.765C>A p.N255K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV99779698; called by muse, mutect2, varscan2
- NPAP1 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.138); catalogued as COSV100276199; called by muse, mutect2, varscan2
- NPAS1 | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV101496972; called by muse, mutect2, varscan2
- NR4A2 | c.1690A>T p.T564S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.021); catalogued as COSV100277386; called by muse, mutect2, varscan2
- NRK | c.1506G>T p.Q502H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99689187; called by muse, mutect2, varscan2
- NRXN1 | c.1381C>G p.P461A | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.208); catalogued as COSV100456868, COSV58471840; called by muse, mutect2
- NTRK3 | c.763C>A p.Q255K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.017); catalogued as COSV100448080, COSV58129470; called by muse, mutect2
- OR4A15 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as rs770091993, COSV59036350; called by muse, mutect2, varscan2
- OR4B1 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs776256251, COSV58883496; called by muse, mutect2, varscan2
- OR4C46 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as COSV60218358; called by muse, mutect2
- OR4N2 | c.825C>A p.H275Q | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100270024; called by muse, mutect2
- OR51B2 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1564906661, COSV100173527; called by muse, mutect2, varscan2
- OR56A4 | c.607G>T p.V203F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.586); catalogued as COSV100417695; called by muse, mutect2, varscan2
- OR5H6 | c.168G>T p.M56I (on ENST00000642105; = p.M40I on NM_001005479.2) | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV67351358, COSV67351638; called by muse, mutect2, varscan2
- OR8D4 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV58430321; called by muse, mutect2
- OR8K3 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 8/140 reads (6%) | catalogued as COSV100449906; called by muse, mutect2
- P2RY10 | c.987G>T p.M329I | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV99409400; called by muse, mutect2, varscan2
- PCDHA10 | c.1279C>G p.R427G | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as rs1554149849, COSV100254468, COSV56507222; called by muse, mutect2
- PCDHGA8 | c.2258A>T p.Y753F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV99546997; called by muse, mutect2, varscan2
- PDCL3 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs771734941, COSV51808582; called by muse, mutect2, varscan2
- PDCL3 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV51808640, COSV99959706; called by muse, mutect2, varscan2
- PDE1C | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100373844; called by muse, mutect2, varscan2
- PDIA3 | c.923G>T p.S308I | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.134); catalogued as COSV100295315; called by muse, mutect2
- PDZRN4 | c.2687A>G p.D896G (on ENST00000402685 / NM_001164595.2; = p.D638G on NM_013377.4) | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209175162, COSV100115466; called by muse, mutect2
- PGAP6 | c.2241G>T p.W747C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99170798; called by muse, mutect2, varscan2
- PIK3C3 | c.820G>C p.A274P | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100011609; called by muse, mutect2, varscan2
- PPP2R2B | c.168G>T p.E56D (on ENST00000394409; = p.E122D on NM_181674.2) | Missense Mutation (SNP) | VAF 55/403 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.274); catalogued as COSV100354262, COSV100356279; called by muse, mutect2, varscan2
- PPP2R5D | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100028993; called by muse, mutect2
- PPP6C | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as COSV101001252; called by muse, mutect2, varscan2
- PRDM2 | c.5102G>T p.R1701M | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV99342696; called by muse, mutect2
- PRDM9 | c.440A>T p.Q147L | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.161); catalogued as COSV99691260; called by muse, mutect2
- PRDM9 | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99691262; called by muse, mutect2
- PRDM9 | c.2464C>A p.H822N | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99691265; called by muse, varscan2
- PREX1 | c.4937G>T p.R1646L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100905974, COSV100906818; called by muse, mutect2, varscan2
- PROKR2 | c.1026G>T p.K342N | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99450641; called by muse, mutect2, varscan2
- PRRX1 | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV53419644, COSV99510335; called by muse, mutect2
- PRSS23 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99722581; called by muse, mutect2
- PRUNE2 | c.6119C>T p.P2040L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs1239232496, COSV100945137; called by muse, mutect2, varscan2
- PTPRT | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100630486; called by muse, mutect2, varscan2
- PUDP | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.622); catalogued as COSV101128308; called by muse, mutect2, varscan2
- QRICH1 | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100676981; called by muse, mutect2
- RALGAPB | c.3043A>C p.N1015H | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV99485820; called by muse, mutect2
- RBBP6 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100154971, COSV60503639; called by muse, mutect2
- RFX7 | c.2969A>T p.Q990L (on ENST00000559447 / NM_001368074.1; = p.Q1087L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV100429437; called by muse, mutect2, varscan2
- RHCG | c.1170G>T p.Q390H | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51515965, COSV99174273; called by muse, mutect2, varscan2
- RLF | c.4445T>A p.V1482E | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101035696; called by muse, mutect2
- RNASE11 | c.281A>C p.D94A | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100250626; called by muse, mutect2
- RYR2 | c.4054G>T p.G1352C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV100767329; called by muse, mutect2, varscan2
- RYR2 | c.4055G>T p.G1352V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.421); catalogued as COSV100772253; called by muse, mutect2, varscan2
- SEC14L3 | c.859G>T p.G287C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99307315; called by muse, mutect2, varscan2
- SEC16B | c.783G>T p.Q261H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100381946; called by muse, mutect2, varscan2
- SEC24A | c.1039G>T p.G347C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs778797719, COSV100524686; called by muse, mutect2, varscan2
- SELP | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1408148474, COSV99741145; called by muse, mutect2
- SEMA6D | c.538+1G>T p.X180_splice | Splice Site (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100317633; called by muse, mutect2, varscan2
- SERPINB4 | c.664G>C p.A222P | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV100346007; called by muse, mutect2, varscan2
- SETD5 | c.1223A>C p.N408T | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100201136; called by muse, mutect2
- SEZ6L | c.1319A>G p.H440R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99962927; called by muse, mutect2, varscan2
- SGCZ | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.202); catalogued as COSV66046658; called by muse, mutect2, varscan2
- SHANK1 | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV99522065; called by muse, mutect2, varscan2
- SLC17A6 | c.1258G>T p.V420L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV99582424; called by muse, mutect2, varscan2
- SLC26A3 | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs770617449, COSV100385297; called by muse, mutect2, varscan2
- SLC39A12 | c.1694C>A p.S565* (on ENST00000377369 / NM_001145195.2; = p.S528* on NM_152725.3) | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | catalogued as COSV101070178, COSV101070221; called by muse, mutect2, varscan2
- SLITRK4 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.241); catalogued as COSV62026357; called by muse, mutect2, varscan2
- SMARCA4 | c.3476G>C p.G1159A | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100759118, COSV60790558; called by muse, mutect2
- SNAP91 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99536628; called by muse, mutect2
- SRGAP1 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV100755143, COSV61894519; called by muse, mutect2, varscan2
- SRRM1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs1376825872, COSV100105164; called by muse, mutect2, varscan2
- SSPOP | n.15492G>A | Splice Region (SNP) | VAF 5/12 reads (42%) | catalogued as rs1201371177, COSV100948047; called by muse, mutect2, varscan2
- STC1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV99282493; called by muse, mutect2, varscan2
- STUM | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100828339, COSV64685487; called by muse, mutect2
- SULT4A1 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99970703, COSV99970729; called by muse, mutect2, varscan2
- SYPL2 | c.625A>G p.M209V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.192); catalogued as rs781772297, COSV63994732; called by muse, mutect2, varscan2
- SYPL2 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV63993267; called by muse, mutect2
- SYT13 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs771532112, COSV50072562; called by muse, mutect2, varscan2
- TAF1L | c.1703G>T p.R568M | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54270050, COSV99645417; called by muse, mutect2, varscan2
- TCAF2 | c.1092G>T p.W364C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100633738; called by mutect2, varscan2
- TDRD5 | c.2272G>T p.A758S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.156); catalogued as COSV54242045, COSV99677172; called by muse, mutect2, varscan2
- TENM1 | c.6275C>A p.T2092N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100950960; called by muse, mutect2, varscan2
- TENM1 | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.697); catalogued as COSV100950963, COSV64432736; called by muse, mutect2, varscan2
- TNS1 | c.5070C>G p.F1690L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371703783, COSV99411905; called by muse, mutect2, varscan2
- TRIM28 | c.2388G>A p.M796I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV99449439; called by muse, mutect2
- TRRAP | c.2239G>C p.A747P | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100722672, COSV100722975; called by muse, mutect2, varscan2
- TSGA10 | c.1378G>T p.D460Y | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100747595; called by muse, mutect2, varscan2
- TSHZ3 | c.2606C>A p.S869Y | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV99552749; called by muse, mutect2
- TTN | c.98254A>T p.T32752S (on ENST00000591111; = p.T25328S on NM_003319.4) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | PolyPhen benign (0.068); catalogued as COSV100630198; called by muse, mutect2, varscan2
- USH2A | c.50T>C p.I17T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs942541689, COSV100242693; called by muse, mutect2, varscan2
- USP29 | c.1960C>A p.Q654K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.31); catalogued as COSV99518666; called by muse, mutect2, varscan2
- VARS1 | c.3320C>G p.A1107G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV100791859, COSV63304977; called by muse, mutect2, varscan2
- VWF | c.2856C>A p.H952Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV54627557, COSV99780159; called by muse, mutect2, varscan2
- WDR62 | c.1837G>T p.G613C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as COSV99544240; called by mutect2, varscan2
- WNK1 | c.6495G>T p.Q2165H (on ENST00000315939 / NM_018979.4; = p.Q1917H on NM_014823.3) | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); catalogued as COSV100268671; called by muse, mutect2, varscan2
- XIRP2 | c.9182C>A p.P3061H (on ENST00000628543; = p.P3236H on NM_152381.6) | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99747455; called by muse, mutect2
- YLPM1 | c.3301_3302insT p.Q1101Lfs*31 | Frame Shift Ins (INS) | VAF 11/71 reads (15%) | catalogued as COSV99461370; called by mutect2, pindel, varscan2
- ZC4H2 | c.544C>A p.Q182K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100565228; called by muse, mutect2
- ZDBF2 | c.3961G>T p.G1321C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV100985552; called by muse, mutect2, varscan2
- ZNF208 | c.3371C>A p.T1124K | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs202182044, COSV101237209, COSV68110370; called by muse, mutect2, varscan2
- ZNF418 | c.1633A>T p.K545* | Nonsense Mutation (SNP) | VAF 15/117 reads (13%) | catalogued as COSV101269021; called by muse, mutect2, varscan2
- ZNF573 | c.1531G>A p.G511R (on ENST00000536220 / NM_001172692.1; = p.G453R on NM_152360.3) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100265849; called by muse, mutect2
- ZNF615 | c.2134G>T p.D712Y | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV100943976; called by muse, mutect2, varscan2
- ZNF804A | c.3461G>T p.R1154M | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100170217; called by muse, mutect2
- ZNF99 | c.2061C>A p.N687K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs776239779, COSV68055056, COSV68056109; called by muse, mutect2, varscan2
- ZNHIT6 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100995666; called by muse, mutect2
- ZSWIM8 | c.4834G>A p.V1612M (on ENST00000605216 / NM_001242487.2; = p.V1617M on NM_015037.3) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.118); catalogued as COSV100014293, COSV100014378; called by muse, mutect2, varscan2
- ALDH1A3 | c.124del p.E42Nfs*53 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- BIVM-ERCC5 | c.4625dup p.L1542Ffs*11 | Frame Shift Ins (INS) | VAF 7/64 reads (11%) | called by mutect2, varscan2
- C7orf31 | c.120_127del p.A41Gfs*14 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- CTCFL | c.4del p.A2Qfs*20 | Frame Shift Del (DEL) | VAF 46/247 reads (19%) | called by pindel, varscan2
- CTNND2 | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FLI1 | c.338del p.P113Lfs*5 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- HOXB8 | c.558dup p.E187Rfs*117 | Frame Shift Ins (INS) | VAF 11/106 reads (10%) | called by mutect2, pindel, varscan2
- HTR1A | c.400A>T p.R134W | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEB6B | c.1168C>G p.L390V | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- MAGEC1 | c.362del p.G121Vfs*21 | Frame Shift Del (DEL) | VAF 25/191 reads (13%) | called by mutect2, pindel, varscan2
- PSME4 | c.4314del p.K1439Nfs*14 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- TFAP2B | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); called by muse, mutect2
- TMEM205 | c.144_172del p.V49Pfs*? | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- TRIP12 | c.1375_1376del p.I459* | Frame Shift Del (DEL) | VAF 15/131 reads (11%) | called by mutect2, pindel, varscan2
- ABCA9 | c.708A>T p.T236= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100383493, COSV60629902; called by muse, mutect2, varscan2
- ADCY2 | c.2811G>A p.K937= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100604134; called by muse, mutect2, varscan2
- ADGRG2 | c.2943T>A p.T981= (on ENST00000379869 / NM_001079858.3; = p.T978= on NM_005756.4) | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV100492699; called by muse, mutect2, varscan2
- ALG10 | c.690C>T p.F230= | Silent (SNP) | VAF 22/223 reads (10%) | catalogued as rs917999095, COSV99848352; called by muse, mutect2, varscan2
- AMFR | c.678G>T p.V226= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99316230; called by muse, mutect2, varscan2
- ARHGAP21 | c.2742A>T p.S914= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100256670; called by muse, mutect2, varscan2
- ARHGAP9 | c.2085G>T p.V695= (on ENST00000393797 / NM_001319850.2; = p.V676= on NM_032496.4) | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99954709; called by muse, mutect2, varscan2
- ARMCX3 | c.307C>A p.R103= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV100362336; called by muse, mutect2, varscan2
- BTNL2 | c.579C>A p.I193= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100896204; called by muse, mutect2, varscan2
- CAMK2B | c.1149C>T p.V383= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99323542; called by muse, mutect2, varscan2
- CARD6 | c.2586A>G p.A862= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as COSV54566415, COSV99621314; called by muse, mutect2
- CDH10 | c.267C>A p.L89= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100053029; called by muse, mutect2, varscan2
- CHRND | c.780C>T p.I260= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV51318029; called by muse, mutect2, varscan2
- CNST | c.495G>T p.A165= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as COSV100829925, COSV63620160; called by muse, mutect2, varscan2
- COL4A6 | c.885C>T p.I295= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100565041; called by muse, mutect2
- CPO | c.111G>T p.V37= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99786665; called by muse, mutect2, varscan2
- CTNND2 | c.975C>G p.G325= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV100481079; called by muse, mutect2
- CUBN | c.2139G>T p.T713= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100913533; called by mutect2, varscan2
- CYP2A13 | c.1446G>T p.T482= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV100387024, COSV57837548; called by muse, mutect2, varscan2
- DEF6 | c.1776C>A p.G592= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as COSV100359531; called by muse, mutect2, varscan2
- FAM83B | c.2493G>A p.K831= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100175019; called by muse, mutect2, varscan2
- FLT1 | c.2766G>A p.K922= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99167049; called by muse, mutect2, varscan2
- GARNL3 | c.138C>T p.V46= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- GARRE1 | c.2610A>G p.P870= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100209759; called by muse, mutect2, varscan2
- HDAC6 | c.318G>T p.P106= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100491270; called by muse, mutect2
- IL17A | c.447G>T p.P149= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs756027794, COSV100391663, COSV60685690; called by muse, mutect2, varscan2
- JADE3 | c.903C>T p.S301= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV99510298; called by muse, mutect2, varscan2
- KCNG1 | c.258G>A p.L86= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100857178; called by muse, mutect2, varscan2
- KCNJ16 | c.297T>C p.H99= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV99388737; called by muse, mutect2, varscan2
- KLHL34 | c.105C>A p.T35= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV101069999, COSV65279945; called by muse, mutect2
- LAX1 | c.420G>A p.E140= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV65850204; called by muse, mutect2, varscan2
- LRRC37A3 | c.513C>T p.S171= | Silent (SNP) | VAF 14/537 reads (3%) | called by muse, mutect2
- MMD2 | c.207C>A p.A69= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV101287149; called by muse, mutect2
- NBEA | c.6513C>G p.L2171= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs779170017, COSV100084227, COSV59791022; called by muse, mutect2, varscan2
- NIM1K | c.61C>A p.R21= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as rs55664335, COSV100390151, COSV58140478; called by muse, mutect2, varscan2
- NSMAF | c.696G>T p.V232= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV50701575; called by muse, mutect2, varscan2
- NTM | c.321G>T p.V107= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100869544; called by muse, mutect2
- NUP210L | c.5451C>A p.T1817= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99669130; called by muse, mutect2, varscan2
- OR6B1 | c.877C>A p.R293= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV101281672, COSV68770172; called by muse, mutect2, varscan2
- OR6C68 | c.37C>T p.L13= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as COSV101110058; called by muse, mutect2, varscan2
- ORAI1 | c.141G>T p.P47= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100345502; called by muse, mutect2, varscan2
- PCDH11X | c.1308A>G p.L436= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as COSV100015315; called by muse, mutect2, varscan2
- PDE1C | c.411G>T p.G137= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV100373846, COSV100374280; called by muse, mutect2, varscan2
- PRKG1 | c.546G>T p.G182= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as rs73336216, COSV100909631; called by mutect2, varscan2
- PROX2 | c.867C>A p.P289= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV101507828; called by muse, mutect2, varscan2
- RBBP6 | c.333G>T p.L111= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100154970; called by muse, mutect2
- RYR2 | c.1260G>T p.R420= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV100772903; called by muse, mutect2, varscan2
- RYR3 | c.5997G>A p.A1999= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs142550033, COSV101213239, COSV66784909; ClinVar: likely benign; called by mutect2, varscan2
- SHANK1 | c.2244G>T p.T748= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV99522063; called by muse, mutect2, varscan2
- SPATC1 | c.645C>G p.A215= | Silent (SNP) | VAF 4/79 reads (5%) | catalogued as COSV101085320; called by muse, mutect2
- THSD7A | c.798C>A p.P266= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV101448905; called by muse, mutect2, varscan2
- TMLHE | c.828T>C p.Y276= | Silent (SNP) | VAF 32/201 reads (16%) | catalogued as rs781824393, COSV100545097; called by muse, mutect2, varscan2
- TPX2 | c.1065C>T p.P355= | Silent (SNP) | VAF 43/183 reads (23%) | catalogued as COSV100302091; called by muse, mutect2, varscan2
- TTN | c.79941T>A p.I26647= (on ENST00000591111; = p.I19223= on NM_003319.4) | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100630201; called by muse, mutect2
- UNC79 | c.5127C>T p.N1709= (on ENST00000393151 / NM_001346218.2; = p.N1532= on NM_020818.5) | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV99829861; called by muse, mutect2, varscan2
- ZNF480 | c.357A>G p.A119= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100574320; called by muse, mutect2
- ZNF641 | c.66G>C p.A22= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV99973682; called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57620303 C>T | 3'Flank (SNP) | VAF 20/486 reads (4%) | catalogued as COSV99678289; called by muse, mutect2
- BCR | c.1279+16099G>T | Intron (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- CLLU1 | chr12:92421150 G>T | 5'Flank (SNP) | VAF 30/149 reads (20%) | catalogued as rs1356728916, COSV101029261, COSV65903253; called by muse, mutect2, varscan2
- ISCA1P1 | n.167G>T | RNA (SNP) | VAF 11/108 reads (10%) | catalogued as rs1034181900; called by muse, mutect2, varscan2
- KIF16B | c.3498+3138C>T | Intron (SNP) | VAF 20/195 reads (10%) | catalogued as COSV100734940; called by muse, mutect2, varscan2
- PSG5 | c.431-3002T>C | Intron (SNP) | VAF 19/222 reads (9%) | catalogued as COSV100743163; called by muse, mutect2
